Gene-level copy-number profile of tumor specimen TCGA-QC-A6FX-01A from TCGA case TCGA-QC-A6FX, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of trunk, NOS; Age at diagnosis: 68.8 years (25,113 days).
Specimen TCGA-QC-A6FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.32a4cbb3-c1d7-408a-8768-9e07a8274020.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QC-A6FX-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5cf68121-7723-4aa4-9253-eea52c4d97e5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 434; copy number 2: 7,229; copy number 3: 7,825; copy number 4: 24,335; copy number 5: 4,885; copy number 6: 7,187; copy number 7: 2,510; copy number 8: 2,619; copy number 9: 1,398; copy number 10: 742; copy number 11: 88; copy number 12: 160; copy number 13: 67; copy number 14: 84; copy number 16: 144; copy number 19: 52; copy number 20: 48; copy number 23: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QC-A6FX-01A-11D-A32H-01): tumor purity 0.7, ploidy 2.21, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,345 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,718,231–177,228,000, 17 genes, copy number 13: UBE2V1P2, RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P.
- chr4:144,505,900–144,509,001, 1 gene, copy number 9: AC106871.1.
- chr4:147,344,629–149,024,624, 18 genes, copy number 10–11 (within-gene range 7–11): MIR548G, AC010683.1, PRMT5P1, EDNRA, AC093908.1, GTF2F2P1, LINC02507, AC093835.1, TMEM184C, PRMT9, ARHGAP10, RNA5SP165, MIR4799, RN7SL254P, AC115621.1, NR3C2, AC069272.1, AC002460.2.
- chr4:148,819,351–151,408,835, 34 genes, copy number 11: AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355, IQCM, AC108168.1, AC093893.1, AKIRIN2P1, RNA5SP167, RNU6-1230P, AC105343.1, AC105343.2, DCLK2, RNU7-194P, LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1, RNA5SP168, AK4P6, RPS3A, SNORD73B, SH3D19, SNORD73A, AC095055.1, AC104819.1, PRSS48, AC104819.2, RNU6-1282P, AC104819.3, FAM160A1-DT.
- chr4:155,173,716–171,525,072, 209 genes, copy number 9–11 (broad region; genes not listed).
- chr6:129,831,244–132,169,374, 32 genes, copy number 10: TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1, MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013.
- chr6:133,502,252–133,892,802, 4 genes, copy number 9 (within-gene range 5–9): TARID, HSPE1P21, AL450270.1, FTH1P26.
- chr6:137,543,897–137,972,522, 11 genes, copy number 10 (within-gene range 7–10): BTF3L4P3, AL356234.2, AL356234.3, AL356234.1, LINC02539, Y_RNA, WAKMAR2, TNFAIP3, AL591468.1, LINC02528, LINC02865.
- chr6:139,271,362–139,667,284, 1 gene, copy number 10 (within-gene range 7–10): AL592429.2.
- chr6:139,435,636–149,411,613, 120 genes, copy number 10–23 (within-gene range 3–23) (broad region; genes not listed).
- chr7:89,754,620–94,077,157, 75 genes, copy number 10 (broad region; genes not listed).
- chr7:95,542,145–111,562,517, 363 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr7:144,397,240–145,270,384, 10 genes, copy number 10: NOBOX, PPIAP83, RNU6ATAC40P, TPK1, EEF1A1P10, RN7SKP174, EI24P4, AC073310.1, RPL7P59, AC004911.1.
- chr9:110,668,779–111,935,369, 23 genes, copy number 10 (within-gene range 6–10): MUSK, AL513328.1, LPAR1, RNU6-432P, Y_RNA, RNY4P18, AL162414.1, MIR7702, OR2K2, ECPAS, RNA5SP294, ZNF483, PTGR1, AL135787.1, LRRC37A5P, DNAJC25, DNAJC25-GNG10, GNG10, SHOC1, AL354877.1, RNU6-1013P, UGCG, MIR4668.
- chr14:18,333,726–36,176,468, 640 genes, copy number 9–16 (broad region; genes not listed).
- chr17:70,628,917–72,237,203, 15 genes, copy number 11 (within-gene range 3–11): AC005771.1, AC007423.1, AC005181.1, CASC17, RNU7-155P, AC118653.1, MYL6P5, AC007432.1, AC005144.1, ROCR, LINC01152, AC007461.1, SOX9-AS1, LINC02097, SOX9.
- chr19:94,062–1,479,219, 98 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr19:38,836,388–44,500,524, 304 genes, copy number 9–14 (within-gene range 6–14) (broad region; genes not listed).
- chr20:34,872,146–35,769,867, 43 genes, copy number 13 (within-gene range 2–13): ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6.
- chr20:38,926,312–42,063,969, 42 genes, copy number 11–14 (within-gene range 2–14): FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1, AL009050.1, MAFB, AL035665.1, AL035665.2, RNA5SP484, RNU2-52P, TOP1, PLCG1-AS1, PLCG1, MIR6871, ZHX3, AL022394.1, RPL23AP81, RN7SL615P, ADI1P1, LPIN3, EMILIN3, AL031667.1, CHD6, AL031667.2, AL031667.3, RPL12P11, RNU6-1018P, AL133229.1, AL049812.2, AL049812.1, AL049812.3.
- chr20:48,624,252–48,827,999, 1 gene, copy number 10 (within-gene range 8–10): PREX1.
- chr20:48,821,688–60,653,784, 229 genes, copy number 10–12 (broad region; genes not listed).
- chr20:63,520,765–64,313,132, 55 genes, copy number 10: PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813, OPRL1, LKAAEAR1, AL121581.3, MYT1, NPBWR2, PCMTD2, AL137028.2, CICP4, LINC00266-1.

Autosomal genes at a single copy (total copy number 1): 434. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
